Somatic mutation profile of tumor specimen TARGET-20-PANDIX-09A (aliquot TARGET-20-PANDIX-09A-02D) from TARGET case TARGET-20-PANDIX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.0 years (6,573 days).
Specimen TARGET-20-PANDIX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3ad2d1f-028b-4932-b5fa-65c389b0f198.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANDIX-14A (Bone Marrow Normal), aliquot TARGET-20-PANDIX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2278df6f-c295-401a-a9ad-7cc01ce99789

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Ins 2, 5'UTR 1, Nonsense Mutation 1, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2
- NRAS | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54738937; called by muse, mutect2
- TAF1L | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750929210, COSV54259693; called by muse, mutect2, varscan2
- TET2 | c.3646C>T p.R1216* | Nonsense Mutation (SNP) | VAF 45/101 reads (45%) | catalogued as rs1009194427, COSV54398925; called by muse, mutect2, varscan2
- TET2 | c.4317dup p.R1440Tfs*38 | Frame Shift Ins (INS) | VAF 22/250 reads (9%) | catalogued as rs777908833; called by mutect2, pindel
- KMT2C | c.8525dup p.N2842Kfs*2 | Frame Shift Ins (INS) | VAF 56/331 reads (17%) | called by mutect2, varscan2
- RLIM | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2
- TET2 | c.5704_5712dup p.Y1902_H1904dup | In Frame Ins (INS) | VAF 42/318 reads (13%) | called by mutect2, varscan2
- TIAM1 | c.1242C>T p.S414= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as rs765934871, COSV54557443; called by muse, mutect2, varscan2
- LRIF1 | c.-223C>A | 5'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
